Somatic mutation profile of tumor specimen TCGA-HT-7485-01A (aliquot TCGA-HT-7485-01A-11D-2024-08) from TCGA case TCGA-HT-7485, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 42.7 years (15,589 days).
Specimen TCGA-HT-7485-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a5c86b7-08ec-41f7-9e2d-51e183f507a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7485-10A (Blood Derived Normal), aliquot TCGA-HT-7485-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77794915-1c63-4dfe-97fb-9c7a4abbcef4

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 10, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 20/25 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.1676A>G p.N559S (on ENST00000372530 / NM_001198934.2; = p.N516S on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs114002465; called by muse, mutect2, varscan2
- ACAP1 | c.1313C>T p.T438I | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV50134045; called by muse, mutect2, varscan2
- ATRX | c.604A>T p.K202* | Nonsense Mutation (SNP) | VAF 51/59 reads (86%) | catalogued as COSV64871022; called by muse, mutect2, varscan2
- LGSN | c.950G>A p.S317N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65726151; called by muse, mutect2, varscan2
- LRP2 | c.4642A>G p.S1548G | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs140722973, COSV55539995; called by muse, mutect2, varscan2
- MCTP2 | c.1241G>A p.G414D | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as rs536270811, COSV59140535; called by muse, mutect2, varscan2
- SEMA6B | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as COSV56702295; called by muse, mutect2, varscan2
- TRIP6 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs777418973, COSV52340878; called by muse, mutect2, varscan2
- WDFY3 | c.9082A>G p.T3028A | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.063); catalogued as COSV55692880; called by muse, mutect2, varscan2
- MYH10 | c.1893C>T p.V631= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV52594746; called by muse, mutect2, varscan2
